Gene-level copy-number profile of tumor specimen ALCH-AF3T-TTP1-A from ALCHEMIST case ALCH-AF3T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.4 years (26,797 days).
Specimen ALCH-AF3T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d2d74f6f-8046-49a7-97ab-9882e5f250c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF3T-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/2e7b8a7b-bfe6-4081-a9d5-9195363001e0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 63; copy number 2: 56,117; copy number 3: 2,056; copy number 4: 2; copy number 5: 140; copy number 7: 20.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 160 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:33,993,646–38,651,035, 158 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr21:43,414,483–43,427,131, 1 gene, copy number 5: SIK1.
- chr21:43,461,960–43,479,534, 1 gene, copy number 5 (within-gene range 2–5): LINC00313.

Autosomal genes at a single copy (total copy number 1): 63. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
